Somatic mutation profile of tumor specimen TCGA-EJ-5504-01A (aliquot TCGA-EJ-5504-01A-01D-1576-08) from TCGA case TCGA-EJ-5504, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.9 years (24,072 days).
Specimen TCGA-EJ-5504-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfbcb609-61d5-4676-9234-cdb68dac6f54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5504-10A (Blood Derived Normal), aliquot TCGA-EJ-5504-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eb3fe30-f1da-41d0-867d-8e73d15b08d5

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA9 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs200651095, COSV65675937; called by muse, mutect2, varscan2
- CILK1 | c.244A>C p.M82L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs1472952242, COSV63154682; called by muse, mutect2, varscan2
- CLDN9 | c.161G>C p.C54S | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746072973, COSV60911058; called by muse, mutect2, varscan2
- CROCC | c.5266C>G p.L1756V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV65012945; called by muse, mutect2, varscan2
- CXCR6 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs771676006, COSV56115534; called by muse, mutect2, varscan2
- DHX32 | c.2176G>T p.E726* | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | catalogued as COSV52941120; called by muse, mutect2, varscan2
- GLRA2 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 53/125 reads (42%) | catalogued as COSV54342596; called by muse, mutect2, varscan2
- IL4R | c.1313G>T p.S438I | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV50141338, COSV50149121; called by muse, mutect2, varscan2
- JAG2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV59310287; called by muse, mutect2, varscan2
- KAT6A | c.2344T>G p.S782A | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV55907662; called by muse, mutect2
- LRBA | c.5188G>A p.A1730T | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63957635; called by muse, mutect2, varscan2
- LRRC15 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.14); catalogued as rs372164095; called by muse, mutect2, varscan2
- MCC | c.1082C>G p.A361G | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56730737; called by muse, mutect2, varscan2
- MMP12 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370884462; called by muse, mutect2, varscan2
- MYH6 | c.2963A>G p.D988G | Missense Mutation (SNP) | VAF 69/360 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV62451924; called by muse, mutect2, varscan2
- NTNG1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs386352339, COSV53976121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ONECUT1 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV59949526; called by muse, mutect2, varscan2
- OR2M3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs199968773, COSV71759103; called by muse, mutect2, varscan2
- PACRGL | c.488T>A p.L163Q | Missense Mutation (SNP) | VAF 60/448 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54843207; called by muse, mutect2, varscan2
- PCDHA13 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 10/336 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56515710; called by muse, mutect2
- PLCB4 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53805810; called by muse, mutect2
- PRPH2 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as CD143729, COSV57837623; called by muse, mutect2, varscan2
- SALL3 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV73305803, COSV73306159; called by muse, mutect2, varscan2
- SNW1 | c.14+7T>C | Splice Region (SNP) | VAF 20/126 reads (16%) | catalogued as rs749834952, COSV55054934; called by muse, mutect2, varscan2
- TEX13B | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV57202208; called by muse, mutect2
- TJP2 | c.1208A>G p.E403G | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV55269000; called by muse, mutect2, varscan2
- TMOD2 | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV51044921; called by muse, mutect2, varscan2
- ZBTB34 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV59860126; called by muse, mutect2, varscan2
- ZSCAN31 | c.581T>A p.I194N | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV60181182; called by muse, mutect2
- DZIP3 | c.669A>G p.E223= | Silent (SNP) | VAF 16/207 reads (8%) | catalogued as COSV64312575; called by muse, mutect2
- ENPP1 | c.2211C>T p.Y737= | Silent (SNP) | VAF 37/239 reads (15%) | catalogued as rs376128399; called by muse, mutect2, varscan2
- HINFP | c.660C>G p.R220= | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as COSV63432220; called by muse, mutect2, varscan2
- NSD2 | c.3858C>T p.D1286= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as rs747413223, COSV56391337; called by muse, mutect2, varscan2
- OR10P1 | c.264G>A p.P88= | Silent (SNP) | VAF 33/197 reads (17%) | catalogued as rs369935856; called by muse, mutect2, varscan2
- PCSK9 | c.897C>T p.A299= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV56162872; called by muse, mutect2, varscan2
- PTPRZ1 | c.3183G>A p.E1061= | Silent (SNP) | VAF 32/235 reads (14%) | catalogued as COSV66439544; called by muse, mutect2, varscan2
- RGS5 | c.369G>A p.T123= | Silent (SNP) | VAF 135/741 reads (18%) | catalogued as rs150796534; called by muse, mutect2, varscan2
- USP37 | c.1515C>A p.L505= | Silent (SNP) | VAF 25/182 reads (14%) | catalogued as COSV51444433; called by muse, mutect2, varscan2
- XKR3 | c.1320C>T p.Y440= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- ZSCAN31 | c.582C>A p.I194= | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as COSV60181165; called by muse, mutect2
